Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A6F0, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A6F0-01A (Primary Tumor).

Department of Cancer Pathology

chc ICD-O-3
Adenocarcinoma, intestinal type
8/14/13
path
Adenocarcinoma w/ mixed
subtypes (papillary, solid, mucinous)
8/25/13
State Cardia NOS c16.5
gw 8/25/13

Patient: XXX

Age:

Gender: F

Examination result

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Cancer of the cardia**

Date of admission:

Material:

1) Material: stomach, Method of collection: Total organ resection

Final result:

Examination performed on:

Stomach adenocarcinoma (G3, pT2, pNO). (8140/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Specimen consisting of the stomach, having been incised along the greater curvature, sized 28.6 x 27.9 cm, with omentum sized 52 x 18 cm and spleen sized 12.2 x 5.8 x 3.9 cm.

In the omentum, spleen with additional diameter of 1 cm and pieces of pancreas sized: 4 x 1, 5 x 2 cm.

Tumour sized 12.8 x 11.7 x 2.9 cm in the cardia region on the back wall.

Distance from the proximal end: 0.4 cm, from distal end: 23 cm.

Microscopic description:

Gastric adenocarcinoma (papillary, partially solid type with some mucous cells (mixed type acc. to Lauren class).

Cancer infiltrated the whole thickness of the stomach wall and fat tissue of the omentum.

Excision lines, omentum and lymph nodes (17) – free of neoplastic lesions.

Spleen and pancreas free of neoplastic lesions.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

IHPAA Discrepancy		☒
Reviewed by: Julia Date Reviewed: 5/20/13		

Source: NCI Genomic Data Commons file a49595f9-21b5-4106-a3f3-cc0ca89f0b5f (TCGA-D7-A6F0.05B4EA94-C05A-493F-862B-48310D4D4399.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).